Somatic mutation profile of tumor specimen TCGA-TM-A84T-01A (aliquot TCGA-TM-A84T-01A-11D-A36O-08) from TCGA case TCGA-TM-A84T, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 19.1 years (6,994 days).
Specimen TCGA-TM-A84T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49fe1ce2-5516-4829-87bb-e078e0bfbde2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84T-10A (Blood Derived Normal), aliquot TCGA-TM-A84T-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1da1115-d38f-494e-9653-b0b9f4ad7f8c

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 13/14 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.3145del p.I1049* | Frame Shift Del (DEL) | VAF 59/96 reads (61%) | catalogued as COSV64885073; called by mutect2, pindel, varscan2
- FAT1 | c.11361C>G p.C3787W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101499679; called by muse, mutect2, varscan2
- GALNT11 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.525); catalogued as rs1325688793, COSV100232094; called by muse, mutect2, varscan2
- HCCS | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100335846; called by muse, mutect2, varscan2
- INTS14 | c.880G>T p.E294* (on ENST00000313182 / NM_001366360.2; = p.E215* on NM_001136043.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100500147; called by muse, mutect2, varscan2
- KRT27 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs755968602, COSV100053408; called by muse, mutect2, varscan2
- MAP1B | c.4106A>G p.K1369R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99703029; called by muse, mutect2, varscan2
- NPRL3 | c.1544G>C p.R515T (on ENST00000611875 / NM_001077350.3; = p.R490T on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99550110; called by muse, mutect2, varscan2
- NUP188 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as rs748122977, COSV101001528; called by muse, mutect2, varscan2
- SDCCAG8 | c.965T>G p.V322G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV100654528, COSV100654728; called by muse, mutect2, varscan2
- SKIL | c.349T>C p.S117P | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as rs904193092, COSV99378613; called by muse, mutect2, varscan2
- SLC8A1 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as COSV100247634, COSV60492889; called by muse, mutect2, varscan2
- TGM5 | c.748G>A p.A250T (on ENST00000220420 / NM_201631.4; = p.A168T on NM_004245.4) | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs113766373, COSV99589399; called by muse, mutect2, varscan2
- THUMPD1 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV101189726; called by muse, mutect2, varscan2
- TIAM1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs775770647, COSV99739581; called by muse, mutect2, varscan2
- TLR7 | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101028194; called by muse, mutect2, varscan2
- ATRX | c.3144A>G p.K1048= | Silent (SNP) | VAF 66/83 reads (80%) | called by mutect2, varscan2
- OR2C3 | c.657C>T p.Y219= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs762023698, COSV63574904; called by muse, mutect2, varscan2
- ZNF335 | c.3975A>G p.Q1325= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs565844838, COSV100533498; called by muse, mutect2, varscan2
